Somatic mutation profile of tumor specimen 0D8ODL from CCDI case PBBHMD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.3 years (5,214 days).
Specimen 0D8ODL: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8469617-dfd7-4f6d-b346-6e25bc72ccf5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D8ODE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7bd62c1f-688b-4a9a-9123-87ba00bb6835

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLNA | c.6991G>A p.D2331N (on ENST00000369850 / NM_001110556.2; = p.D2323N on NM_001456.3) | Missense Mutation (SNP) | VAF 131/385 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as rs371689052; called by muse, varscan2
- MXRA5 | c.3338C>T p.A1113V | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs376165336, COSV99477362; called by muse, varscan2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs1167537044; called by muse, varscan2
- TRHDE | c.2385G>A p.P795= | Silent (SNP) | VAF 32/229 reads (14%) | catalogued as rs574504129; called by muse, varscan2
